Somatic mutation profile of tumor specimen TCGA-24-1603-01A (aliquot TCGA-24-1603-01A-01W-0551-08) from TCGA case TCGA-24-1603, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 53.9 years (19,681 days).
Specimen TCGA-24-1603-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43cf478c-6e0d-4448-99ff-d5bc2aee9a7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1603-10A (Blood Derived Normal), aliquot TCGA-24-1603-10A-01W-0551-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4590e3a-7c1e-4358-bc80-17f2aa637fe8

The open-access MAF lists 37 somatic variants for this specimen: 29 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 7, 5'UTR 1, Frame Shift Ins 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY2 | c.2662G>A p.V888I | Missense Mutation (SNP) | VAF 185/419 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV57869521; called by muse, mutect2, varscan2
- AKNAD1 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 198/477 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.112); catalogued as COSV62200206; called by muse, mutect2, varscan2
- CACNB4 | c.1352A>T p.E451V | Missense Mutation (SNP) | VAF 27/250 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); catalogued as COSV52397178; called by muse, mutect2
- CD79A | c.482C>T p.T161M | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs782414774, COSV55738910; called by muse, mutect2, varscan2
- CHRM3 | c.481G>T p.V161F | Missense Mutation (SNP) | VAF 133/366 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55093948; called by muse, mutect2, varscan2
- DGKD | c.2629G>A p.V877M (on ENST00000264057 / NM_152879.3; = p.V833M on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/493 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs745892049, COSV99897886; called by muse, mutect2
- DNAH11 | c.8559G>T p.L2853F | Missense Mutation (SNP) | VAF 58/349 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60964800; called by muse, mutect2, varscan2
- DOCK4 | c.1339G>C p.G447R | Missense Mutation (SNP) | VAF 131/338 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70323037; called by muse, mutect2, varscan2
- DPF1 | c.1029C>A p.Y343* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as COSV55918006; called by muse, mutect2
- DST | c.3256C>A p.L1086M (on ENST00000361203 / NM_001374722.1; = p.L760M on NM_001723.6) | Missense Mutation (SNP) | VAF 131/305 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV55024093; called by muse, mutect2, varscan2
- FASTKD3 | c.1916C>T p.S639L | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV99242727; called by muse, mutect2
- FBN3 | c.5466G>T p.M1822I | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as COSV99560948; called by muse, mutect2
- GRIK1 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 162/565 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs928204075, COSV58723524; called by muse, mutect2, varscan2
- ITPRIPL1 | c.347G>T p.G116V (on ENST00000439118 / NM_001008949.3; = p.G124V on NM_178495.6) | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as COSV63153167, COSV63153981; called by muse, mutect2, varscan2
- KCNMA1 | c.2675C>T p.T892M (on ENST00000286628 / NM_001161352.2; = p.T834M on NM_002247.4) | Missense Mutation (SNP) | VAF 685/2326 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.391); catalogued as rs200440843, COSV54269078; ClinVar: uncertain significance; called by muse, varscan2
- KLHL4 | c.1576T>A p.Y526N | Missense Mutation (SNP) | VAF 456/505 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64144308, COSV64145053; called by muse, mutect2, varscan2
- LDLR | c.890A>G p.N297S | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as rs1555803887, CD033542, CX1414958, COSV52944281; ClinVar: uncertain significance; called by muse, mutect2
- MEF2B | c.308A>G p.D103G | Missense Mutation (SNP) | VAF 61/129 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as COSV99365180; called by muse, mutect2, varscan2
- PIK3C2G | c.80T>A p.V27E | Missense Mutation (SNP) | VAF 17/292 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.277); catalogued as COSV99854441; called by muse, mutect2
- POLE2 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 272/984 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773570956, COSV53559408; called by muse, mutect2, varscan2
- RTTN | c.6416C>G p.A2139G | Missense Mutation (SNP) | VAF 203/219 reads (93%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV55347745; called by muse, mutect2, varscan2
- SNAI1 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 194/360 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768825298, COSV54864425; called by muse, mutect2, varscan2
- SPTAN1 | c.5909C>T p.A1970V | Missense Mutation (SNP) | VAF 50/56 reads (89%) | SIFT tolerated (0.18); PolyPhen benign (0.188); catalogued as rs772780483, COSV63988204; called by muse, mutect2, varscan2
- ST14 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 59/122 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs749874221, COSV53833723; called by muse, mutect2, varscan2
- TENT5D | c.868G>T p.G290C | Missense Mutation (SNP) | VAF 433/489 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57636815, COSV57639370; called by muse, mutect2, varscan2
- TP53 | c.945dup p.P316Sfs*21 | Frame Shift Ins (INS) | VAF 299/454 reads (66%) | catalogued as COSV52867051; called by mutect2, pindel, varscan2
- TTYH2 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 130/671 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs150383554; called by muse, mutect2, varscan2
- WDR4 | c.1162C>T p.R388W | Missense Mutation (SNP) | VAF 138/145 reads (95%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs756642989, COSV57734240; called by muse, mutect2, varscan2
- RNF213 | c.8955del p.N2986Tfs*32 | Frame Shift Del (DEL) | VAF 32/48 reads (67%) | called by mutect2, pindel, varscan2
- HS3ST2 | c.534G>A p.T178= | Silent (SNP) | VAF 409/932 reads (44%) | catalogued as rs145496461, COSV54460355; called by muse, mutect2, varscan2
- HSPA2 | c.573C>T p.C191= | Silent (SNP) | VAF 7/160 reads (4%) | catalogued as COSV55968626; called by muse, mutect2
- KRT6B | c.1392C>G p.T464= | Silent (SNP) | VAF 47/1390 reads (3%) | catalogued as COSV52886486, COSV99361103; called by muse, mutect2
- LNPEP | c.1209T>C p.F403= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as COSV51479128; called by muse, mutect2, varscan2
- NDUFV1 | c.969T>G p.S323= | Silent (SNP) | VAF 72/160 reads (45%) | catalogued as COSV100295433; called by muse, mutect2, varscan2
- SPPL2B | c.672G>A p.V224= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV101194705; called by mutect2, varscan2
- TSC1 | c.2244G>A p.Q748= | Silent (SNP) | VAF 301/334 reads (90%) | catalogued as COSV53769102; called by muse, mutect2, varscan2
- VPS11 | c.-171A>G | 5'UTR (SNP) | VAF 8/160 reads (5%) | catalogued as COSV100334050; called by muse, mutect2
